MMRF case MMRF_1568 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c034d0c6-4806-44a9-a620-602409ce18f3

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.8 years (24,411 days); ISS stage: II; Days to last known disease status: 1,274 days (3.5 years); Days to last follow up: 1,274 days (3.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 22 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 50 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 29 days; Days to treatment end: 113 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 55 days; Days to treatment end: 113 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 171 days; Days to treatment end: 171 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 173 days; Days to treatment end: 173 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 285 days; Days to treatment end: 441 days (1.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Daratumumab + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,275 days (3.5 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,274.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1140 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.752 mg/dL; Immunoglobulin G 4.42 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 4.52 µg/mL; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 252 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 7.5 g/dL; Glucose 5.72 mmol/L.
- Day 85 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 34.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.762 mg/dL; Hemoglobin 6.08 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 7.7 ×10⁹/L; Platelets 263 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.1 mmol/L; Albumin 33 g/L; Total Protein 6.3 g/dL; Glucose 6.05 mmol/L.
- Day 189 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.302 mg/dL; Immunoglobulin G 3.12 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 2.63 µg/mL; Hemoglobin 7.01 mmol/L; Leukocytes 9.5 ×10⁹/L; Absolute Neutrophil 6.7 ×10⁹/L; Platelets 99 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.15 mmol/L; Albumin 32 g/L; Total Protein 6.4 g/dL; Glucose 7.59 mmol/L.
- Day 285 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.84 mg/dL; Immunoglobulin G 6.95 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 2.96 µg/mL; Hemoglobin 6.26 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 6.7 g/dL; Glucose 3.91 mmol/L.
- Day 350 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.24 mg/dL; Hemoglobin 6.39 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 4.95 mmol/L.
- Day 470 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 5.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Hemoglobin 5.64 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 45 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 6.9 g/dL; Glucose 4.73 mmol/L.
- Day 533 (ECOG 0): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.36 mg/dL; Hemoglobin 5.21 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 42 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 4.62 mmol/L.
- Day 617 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 6.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.44 mg/dL; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 42 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.9 g/dL; Glucose 5.01 mmol/L.
- Day 744 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 7.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.46 mg/dL; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 5.46 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 47 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 6.9 g/dL; Glucose 5.23 mmol/L.
- Day 803 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 11.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.841 mg/dL; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 5.39 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 46 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.08 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 4.79 mmol/L.
- Day 918 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 12.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.54 mg/dL; Hemoglobin 6.45 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 54 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 5.5 mmol/L.
- Day 1,023 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 24.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 67 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 6.9 g/dL; Glucose 4.51 mmol/L.
- Day 1,093 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 29.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Hemoglobin 6.32 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 64 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 6.6 g/dL; Glucose 5.61 mmol/L.
- Day 1,185 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 94.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.15 mg/dL; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 87 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 5.67 mmol/L.
- Day 1,267 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 133 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 7 g/dL; Glucose 5.06 mmol/L.

Other clinical attributes
- Day 1: Weight: 56 kg; Height: 160 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1568_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1568_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
